CCDI case PBBYFL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/f7b27ca3-4e01-41b9-9b1a-c428bcc7a98f

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Myxoid liposarcoma: ICD-O-3 morphology code: 8852/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 14.0 years (5,131 days).

Biospecimens (2 samples)
- Sample 0DNJA0: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DNJB6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
